Gene-level copy-number profile of tumor specimen ALCH-AEEW-TTP1-A from ALCHEMIST case ALCH-AEEW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,245 days).
Specimen ALCH-AEEW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file babab79a-353d-447f-bcad-e745d06a89e8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEEW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/2f0a60a6-1aaf-40b4-b4c6-a775dc0936a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12; copy number 2: 58,200; copy number 3: 163; copy number 4: 1; copy number 5: 3; copy number 7: 3; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,489,860–120,850,985, 7 genes, copy number 5–8 (within-gene range 2–8): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19.
- chr22:18,873,543–18,894,407, 1 gene, copy number 5 (within-gene range 3–5): FAM230F.
- chr22:18,906,028–18,947,732, 3 genes, copy number 7 (within-gene range 4–7): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
